CCDI case PBBMGD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/e3f7985c-f8be-4f58-92e8-6945098d9006

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 14.4 years (5,264 days).

Biospecimens (3 samples)
- Sample 0DCBIR: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DCBIW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DCBJ3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
